Surgical pathology report (de-identified scan), TCGA case TCGA-06-0206, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0206-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0706

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, FRONTAL LOBE, BIOPSY: GLIOBLASTOMA MULTIFORME.
- B. BRAIN, FRONTAL LOBE, BIOPSY: WHITE MATTER WITH GLIOSIS.

SPECIAL STAIN: ADDITIONAL SECTIONS FROM BLOCK #2 WERE IMMUNOSTAINED FOR MIB-1. THE STAIN YIELDS A LABELING INDEX OF 10%.

Operation/Specimen: Lt. frontal lesion - #1; Lt. frontal lesion #2.

Clinical History and Pre-Op Dx: Lt. frontal mass.

GROSS PATHOLOGY: Received unfixed labeled with the patient's name, MRN and "left frontal lesion #1", are two red-tan, glistening, soft, friable, irregular brain tissue fragments measuring 0.4 to 0.6 cm. in greatest dimensions.

Specimen is submitted for frozen section diagnosis.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Brain, left frontal lobe, biopsy: High grade glioma. Frozen section remnant in cassette 1, remaining tissue in cassette 2.

B. Received unfixed labeled with the patient's name, MRN and "left frontal lesion", are two yellow-tan, glistening, soft, irregular brain tissue fragments ranging from 0.3 to 0.6 cm. in greatest dimensions. Entirely submitted in cassette 3.

MICROSCOPIC: The permanent sections confirm the frozen sections diagnosis in part A. Sections from the left frontal lobe lesion shows a high grade glioma, which diffusely infiltrates and replaces the normal brain architecture. The neoplastic cells are small to medium size with occasional giant forms. Neoplastic cells have pleomorphic hyperchromatic nuclei with prominent nucleoli. Occasional mitoses are present. Extensive areas of coagulation necrosis and individual cell

Cont'd....

[page 2 of 2]
necrosis are present within the tumor and adjacent areas. Areas of endothelial hyperplasia are also noted. Additional sections will be submitted for MIB-1 labeling index and the results will be reported as an addendum.

TCGA-06-0206

Sections from specimen B submitted as left frontal lesion shows fragments of white matter with a slight increase in the number of glial cells, which are small, round and uniform reactive astrocytes with abundant eosinophilic cytoplasm. These findings are in keeping with reactive gliosis.

Source: NCI Genomic Data Commons file fb8efc74-a6cc-46d6-99d6-6353e6699665 (TCGA-06-0206.14FC5CCD-AD34-4BD1-8D57-D73303935481.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).